Somatic mutation profile of tumor specimen ALCH-B3E8-TTP1-A (aliquot ALCH-B3E8-TTP1-A-2-0-D-A799-36) from ALCHEMIST case ALCH-B3E8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,820 days).
Specimen ALCH-B3E8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dba0f1a-c4bd-4413-89d2-63241d9955df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3E8-NB1-A (Blood Derived Normal), aliquot ALCH-B3E8-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03a913f4-5475-4d58-9b07-ecec3eff8ed8

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 5'Flank 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 36/898 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.434); catalogued as rs760574070; called by muse, mutect2
- LRRC7 | c.3356C>T p.P1119L (on ENST00000651989 / NM_001370785.2; = p.P1086L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377656393; called by muse, mutect2
- TBC1D32 | c.3181G>A p.G1061R | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1462826124, COSV99249994; called by muse, mutect2
- AGRN | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- APOB | c.11941C>T p.P3981S | Missense Mutation (SNP) | VAF 27/804 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2
- FOXG1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 30/376 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- ISM2 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- MAPRE2 | c.76A>T p.I26F | Missense Mutation (SNP) | VAF 20/648 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.84); called by muse, mutect2
- PITHD1 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPATA16 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- TMEM104 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 20/740 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.385); called by muse, mutect2
- ZFHX4 | c.3252G>C p.Q1084H | Missense Mutation (SNP) | VAF 66/1226 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGAP2 | c.2562G>A p.K854= | Silent (SNP) | VAF 77/448 reads (17%) | catalogued as COSV57731567; called by muse, mutect2, varscan2
- IGF2BP1 | c.57G>A p.E19= | Silent (SNP) | VAF 13/357 reads (4%) | called by muse, mutect2
- TET2 | c.2319A>T p.G773= | Silent (SNP) | VAF 32/931 reads (3%) | called by muse, mutect2
- COA6 | chr1:234373596 G>A | 5'Flank (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- MIR302E | chr11:7238875 C>T | 3'Flank (SNP) | VAF 22/456 reads (5%) | catalogued as rs138631958; called by muse, mutect2
